Somatic mutation profile of tumor specimen TCGA-FG-A710-01A (aliquot TCGA-FG-A710-01A-12D-A33T-08) from TCGA case TCGA-FG-A710, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 50.4 years (18,415 days).
Specimen TCGA-FG-A710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ed451e2-ce00-4cfd-8d03-358db17dc109.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A710-10A (Blood Derived Normal), aliquot TCGA-FG-A710-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ed80e24-6045-4605-9ec7-3b62c7495612

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Nonsense Mutation 3, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 23/239 reads (10%) | catalogued as rs886041116, CM166963, COSV100823721; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 52/153 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB7 | c.1219G>T p.V407F (on ENST00000373394 / NM_001271696.3; = p.V408F on NM_004299.6) | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99504283; called by muse, mutect2
- ASIC5 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV101611129; called by muse, mutect2
- BRWD1 | c.5447C>A p.T1816N | Missense Mutation (SNP) | VAF 20/345 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs747796867, COSV60901808; called by muse, mutect2
- CBWD5 | c.952-1G>A p.X318_splice (on ENST00000382405 / NM_001330668.1; = p.X270_splice on NM_001024916.3) | Splice Site (SNP) | VAF 50/1144 reads (4%) | catalogued as rs1372550546; called by muse, mutect2
- CHST8 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99381020; called by muse, mutect2
- CIC | c.685A>C p.T229P | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99359460; called by muse, mutect2, varscan2
- COL1A1 | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752075205, COSV99867080; called by muse, mutect2, varscan2
- DNMT3A | c.2194T>C p.F732L | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53074204, COSV53085715, COSV99261966; called by muse, mutect2, varscan2
- FUBP1 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 17/187 reads (9%) | catalogued as COSV53941464, COSV99628495; called by muse, mutect2
- H2AC17 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV58154136; called by muse, mutect2, varscan2
- KRTAP10-7 | c.374G>C p.C125S | Missense Mutation (SNP) | VAF 28/546 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs1555928524, COSV100170121; called by muse, mutect2
- MTMR1 | c.1814A>G p.N605S | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100953085; called by muse, mutect2, varscan2
- NAP1L2 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100999202; called by muse, mutect2, varscan2
- NOA1 | c.1672G>T p.V558F | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99950501; called by muse, mutect2
- OR10A7 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 6/192 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV100406554; called by muse, mutect2
- OR1S1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 30/566 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV100515363; called by muse, mutect2
- PJA2 | c.757A>G p.S253G | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100754412; called by muse, mutect2, varscan2
- PLEKHM3 | c.2024G>A p.S675N | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV101216504; called by muse, mutect2, varscan2
- RECQL4 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1060501375, COSV52883054, COSV99467482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA6B | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 8/164 reads (5%) | catalogued as COSV56704017; called by muse, mutect2
- SLC25A15 | c.410T>C p.M137T | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1273050089, COSV100090857; called by muse, mutect2, varscan2
- SYT10 | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.364); catalogued as rs1177627127, COSV99951269; called by muse, mutect2, varscan2
- WNK3 | c.4790G>A p.R1597Q | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs958055900, COSV63615790; called by muse, mutect2, varscan2
- DDX47 | c.1296_1298del p.D433del | In Frame Del (DEL) | VAF 28/90 reads (31%) | called by pindel, varscan2
- ANKRD29 | c.165C>T p.Y55= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as rs1361688706, COSV52427040; called by muse, varscan2
- AQP10 | c.225C>T p.N75= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs1277254743, COSV100270175; called by muse, mutect2, varscan2
- CIR1 | c.426A>G p.E142= | Silent (SNP) | VAF 23/274 reads (8%) | catalogued as rs1559061622, COSV100564957; called by muse, mutect2
- ELAC2 | c.936A>G p.P312= | Silent (SNP) | VAF 41/379 reads (11%) | catalogued as COSV100568474; called by muse, mutect2, varscan2
- KRTAP19-8 | c.90C>T p.G30= | Silent (SNP) | VAF 26/312 reads (8%) | catalogued as COSV101239187; called by muse, mutect2
- LRRC45 | c.1872T>C p.S624= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100141797; called by muse, mutect2, varscan2
- PCDHA3 | c.1854G>A p.A618= | Silent (SNP) | VAF 92/186 reads (49%) | catalogued as rs1554122551, COSV63538759; called by muse, mutect2, varscan2
- PCDHGB1 | c.1713C>T p.F571= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV53997035; called by muse, mutect2, varscan2
- PCDHGB2 | c.1953G>A p.Q651= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV99536792; called by muse, mutect2, varscan2
- SAGE1 | c.660C>T p.N220= | Silent (SNP) | VAF 152/682 reads (22%) | catalogued as rs781786662, COSV100187113; called by muse, mutect2, varscan2
- SOAT1 | c.1042T>C p.L348= | Silent (SNP) | VAF 18/360 reads (5%) | catalogued as COSV100858940; called by muse, mutect2
- TMPRSS11B | c.597G>A p.Q199= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV100219327; called by muse, mutect2, varscan2
- ZBTB9 | c.600A>C p.G200= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as COSV101221749; called by muse, mutect2, varscan2
- LBHD1 | c.617-592T>G | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100649103; called by mutect2, varscan2
